Somatic mutation profile of tumor specimen TCGA-BG-A0M8-01A (aliquot TCGA-BG-A0M8-01A-12D-A10B-09) from TCGA case TCGA-BG-A0M8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 50.1 years (18,308 days).
Specimen TCGA-BG-A0M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 799c241d-83cf-4d81-98cf-2c5410c5e19c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M8-10A (Blood Derived Normal), aliquot TCGA-BG-A0M8-10A-01D-A10O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03ae53d3-8989-4395-b7b6-7e4409821f02

The open-access MAF lists 77 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Nonsense Mutation 6, In Frame Del 2, Frame Shift Del 2, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3143A>G p.H1048R | Missense Mutation (SNP) | VAF 156/306 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1553826184, COSV55889761, COSV55984388; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1370_1381del p.Q457_S460del (on ENST00000521381 / NM_181523.3; = p.Q187_S190del on NM_181504.4) | In Frame Del (DEL) | VAF 35/127 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 178/367 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.117A>T p.K39N | Missense Mutation (SNP) | VAF 68/654 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61615242; called by muse, mutect2, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, mutect2, varscan2
- ARSG | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 184/383 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71593723; called by muse, mutect2, varscan2
- ASB13 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV63091613; called by muse, mutect2, varscan2
- ATG2A | c.4822A>G p.I1608V | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV65967819; called by muse, mutect2, varscan2
- ATP4A | c.18C>A p.N6K | Missense Mutation (SNP) | VAF 29/589 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1432550124, COSV52870023; called by muse, mutect2
- BGN | c.298A>G p.N100D | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59037692; called by muse, mutect2, varscan2
- CAPG | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55708179; called by muse, mutect2, varscan2
- CD226 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 34/246 reads (14%) | catalogued as COSV54614386; called by muse, mutect2, varscan2
- CUL9 | c.3164A>T p.Q1055L | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52731719; called by muse, mutect2
- DBN1 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52791309; called by muse, mutect2
- EGR3 | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100416314, COSV57834117; called by muse, mutect2, varscan2
- ETF1 | c.694T>G p.F232V | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV62127799; called by muse, mutect2
- FAM71D | c.72T>G p.H24Q | Missense Mutation (SNP) | VAF 165/333 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61296144; called by muse, mutect2, varscan2
- FATE1 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV64849151; called by muse, mutect2, varscan2
- FZD3 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 200/497 reads (40%) | catalogued as COSV53536827; called by muse, mutect2, varscan2
- GPR61 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.091); catalogued as COSV63984211; called by muse, mutect2
- IGFN1 | c.1295C>T p.A432V (on ENST00000295591 / NM_001367841.1; = p.A2889V on NM_001164586.2) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV55178947; called by muse, mutect2, varscan2
- KCMF1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778373979, COSV69054361; called by muse, mutect2, varscan2
- KRAS | c.59C>G p.T20R | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55571100, COSV55887952; called by muse, mutect2, varscan2
- KRT84 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57772688; called by muse, mutect2, varscan2
- LAMA3 | c.8621G>C p.R2874T (on ENST00000313654 / NM_198129.4; = p.R1265T on NM_000227.6) | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.777); catalogued as COSV52539105; called by muse, mutect2, varscan2
- LILRB2 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 31/245 reads (13%) | catalogued as COSV58747084; called by muse, mutect2, varscan2
- LIMA1 | c.1668G>A p.W556* | Nonsense Mutation (SNP) | VAF 40/370 reads (11%) | catalogued as COSV57964873; called by muse, mutect2, varscan2
- LVRN | c.753T>A p.F251L | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV63497842; called by muse, mutect2
- LZTR1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs776893978, COSV53146917; called by muse, mutect2, varscan2
- MAGEL2 | c.2887G>A p.A963T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776392903, COSV58568227; called by muse, mutect2, varscan2
- METTL8 | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 121/628 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.048); catalogued as COSV64548807, COSV64550750; called by muse, mutect2, varscan2
- OR52N2 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 33/190 reads (17%) | catalogued as COSV57676764, COSV57677386; called by muse, mutect2, varscan2
- OR52N4 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as rs764640682, COSV57891968; called by muse, mutect2, varscan2
- PDZD4 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51248902; called by muse, mutect2, varscan2
- PKD1L1 | c.7442C>A p.P2481H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51843674; called by muse, mutect2, varscan2
- PRDM14 | c.1710C>G p.D570E | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV52573959; called by muse, mutect2, varscan2
- PSKH1 | c.1081T>G p.S361A | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52124287; called by muse, mutect2, varscan2
- RBM5 | c.2399A>G p.K800R | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as COSV61738389; called by muse, varscan2
- RNF10 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV58046906, COSV58047243; called by muse, mutect2, varscan2
- RPS29 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 124/202 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV55420754, COSV55421298; called by muse, mutect2, varscan2
- SLAMF7 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 29/892 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV63563709; called by muse, mutect2
- SLC6A14 | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 25/720 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV64147907; called by muse, mutect2
- SLC7A5 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55365919; called by muse, mutect2, varscan2
- SSX5 | c.69+1G>T p.X23_splice | Splice Site (SNP) | VAF 89/786 reads (11%) | catalogued as COSV61255920, COSV61256754; called by muse, mutect2, varscan2
- STIP1 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59440085; called by muse, mutect2, varscan2
- TDRD9 | c.1486C>G p.R496G | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59151612; called by muse, mutect2, varscan2
- TG | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 92/299 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs144254329, COSV55086672; called by muse, mutect2, varscan2
- TMEM65 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52631390; called by muse, mutect2, varscan2
- VEZT | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV54142233; called by mutect2, varscan2
- VIRMA | c.2248G>T p.D750Y | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV52588437; called by muse, mutect2, varscan2
- ZNF112 | c.1966C>G p.Q656E (on ENST00000337401 / NM_001083335.2; = p.Q650E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100496494, COSV61621315; called by muse, mutect2
- ZNF250 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 111/546 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52970059; called by muse, mutect2, varscan2
- ZNF71 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs776719783, COSV60149103; called by muse, mutect2, varscan2
- FYN | c.97_113del p.D33Lfs*54 | Frame Shift Del (DEL) | VAF 41/384 reads (11%) | called by mutect2, pindel, varscan2
- ME2 | c.1282_1314del p.C428_E438del | In Frame Del (DEL) | VAF 30/224 reads (13%) | called by mutect2, pindel
- UPF3A | c.1384del p.A462Qfs*54 | Frame Shift Del (DEL) | VAF 72/237 reads (30%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.1077C>T p.S359= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs1307411170, COSV66360619; called by muse, mutect2, varscan2
- ADAT1 | c.114G>A p.V38= | Silent (SNP) | VAF 50/241 reads (21%) | catalogued as COSV57187633; called by muse, mutect2, varscan2
- AMER3 | c.1009A>C p.R337= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV58468471; called by muse, mutect2, varscan2
- CAPZB | c.291G>A p.E97= | Silent (SNP) | VAF 77/272 reads (28%) | catalogued as COSV51649833, COSV99940225; called by muse, mutect2, varscan2
- CTNNA1 | c.2670C>T p.H890= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as rs528674508, COSV57078210; called by muse, mutect2, varscan2
- DMKN | c.375A>G p.A125= | Silent (SNP) | VAF 133/377 reads (35%) | catalogued as COSV60087998; called by muse, mutect2, varscan2
- DPYSL5 | c.138C>T p.G46= | Silent (SNP) | VAF 118/241 reads (49%) | catalogued as rs761018813, COSV56511644; called by muse, mutect2, varscan2
- MBTD1 | c.1602T>C p.D534= | Silent (SNP) | VAF 45/333 reads (14%) | catalogued as COSV64502702; called by muse, mutect2, varscan2
- MEF2D | c.1293C>T p.T431= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV61729654; called by muse, mutect2, varscan2
- NETO1 | c.591C>T p.S197= | Silent (SNP) | VAF 107/290 reads (37%) | catalogued as rs775844376, COSV55011126; called by muse, mutect2, varscan2
- OR4C46 | c.624C>T p.N208= | Silent (SNP) | VAF 57/391 reads (15%) | catalogued as COSV60219752, COSV60220523; called by muse, mutect2, varscan2
- PCDHA6 | c.1869C>T p.R623= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV65343284; called by muse, mutect2
- PDE10A | c.1050C>T p.V350= | Silent (SNP) | VAF 113/626 reads (18%) | catalogued as COSV63101989; called by muse, mutect2, varscan2
- RNF40 | c.2895C>T p.H965= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as rs375969920; called by muse, mutect2
- SUPT20H | c.580T>C p.L194= (on ENST00000350612 / NM_001014286.3; = p.L195= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/276 reads (36%) | catalogued as COSV62248770; called by muse, mutect2, varscan2
- TEKT4 | c.882C>G p.R294= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV54626726; called by muse, mutect2, varscan2
- TTN | c.41178T>C p.D13726= (on ENST00000591111; = p.D6302= on NM_003319.4) | Silent (SNP) | VAF 86/264 reads (33%) | catalogued as COSV60206953; called by muse, mutect2, varscan2
- WDR62 | c.2913G>A p.Q971= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV54332164, COSV54337458; called by muse, mutect2, varscan2
- XYLT1 | c.2628C>T p.N876= | Silent (SNP) | VAF 88/297 reads (30%) | catalogued as COSV54491108; called by muse, mutect2, varscan2
- BIRC8 | n.1651T>G | RNA (SNP) | VAF 28/306 reads (9%) | catalogued as COSV58844063; called by muse, mutect2
- CTBP2 | c.58+12513G>A | Intron (SNP) | VAF 48/98 reads (49%) | catalogued as rs140138824; called by muse, mutect2, varscan2
